Gene-level copy-number profile of tumor specimen TCGA-VF-A8AB-01A from TCGA case TCGA-VF-A8AB, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 31.9 years (11,659 days).
Specimen TCGA-VF-A8AB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.9df72d64-cd58-4eb3-a42d-3d53a23c262d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VF-A8AB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/93f785f7-02a6-4f9c-922f-f677b0bb4663

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 618; copy number 2: 14,736; copy number 3: 3,378; copy number 4: 30,562; copy number 5: 9,316; copy number 6: 169; copy number 7: 329; copy number 9: 113; copy number 10: 210; copy number 15: 50; copy number 18: 154; copy number 20: 38; copy number 24: 147.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VF-A8AB-01A-31D-A434-01): tumor purity 0.3, ploidy 2.95, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 712 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:151,085,697–151,437,072, 1 gene, copy number 9 (within-gene range 6–9): MED12L.
- chr3:151,212,117–155,258,766, 58 genes, copy number 9 (within-gene range 6–9): P2RY14, SETP11, AC078816.1, GPR87, P2RY13, P2RY12, IGSF10, MRPL42P6, AC117454.1, MIR5186, LINC02066, AADACL2, AADACL2-AS1, AC068647.1, AADACP1, AC068647.2, AADAC, SUCNR1, AC108718.1, MBNL1, MBNL1-AS1, TMEM14EP, Y_RNA, AC026347.1, AC092924.1, AC092924.2, ATP5MGP5, P2RY1, HMGN2P13, AC117394.1, AC117394.2, RAP2B, RN7SL300P, AC078788.1, AC078788.2, LINC02006, LINC02877, RNU6-901P, Y_RNA, AC068985.1, U8, RPL21P42, ARHGEF26-AS1, ARHGEF26, DHX36, AC134026.1, AC134026.2, GPR149, DDX50P2, AC092994.1, SYPL1P1, DYNLL1P5, RPL9P15, AC073359.2, AC073359.1, MME, MME-AS1, LINC01487.
- chr3:167,239,843–170,181,749, 54 genes, copy number 9: ZBBX, LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26, GOLIM4, AC069243.1, EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P.
- chr12:7,890,801–34,249,958, 599 genes, copy number 10–24 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 611. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
